HCMI case HCM-CSHL-0768-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/d341953c-f4a1-4c6b-ac1a-50f1b956c696

Demographics
Sex at birth: female; Days to birth: -19,710 days (54.0 years before the index date); Year of birth: 1965.

Diagnoses (5)
1. Serous surface papillary carcinoma (the primary disease): ICD-O-3 morphology code: 8461/3; ICD-10 code: C56.1; Tissue or organ of origin: Ovary; Classification of tumor: primary; FIGO stage: Stage II; Tumor grade: High Grade; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Omentum / Colon, NOS / Diaphragm / Spleen.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C79.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Colon, NOS; Classification of tumor: metastasis; Sites of involvement: Omentum / Diaphragm / Spleen.
3. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C79.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Spleen; Classification of tumor: metastasis; Sites of involvement: Omentum / Colon, NOS / Diaphragm.
4. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C79.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: metastasis; Sites of involvement: Colon, NOS / Diaphragm / Spleen.
5. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C79.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of thorax; Classification of tumor: metastasis; Sites of involvement: Omentum / Colon, NOS / Spleen.

Follow-up (5 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Colon, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Spleen; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of thorax; Days to progression: 0 days.
- Follow-up contact recording only the day: day 152.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 173 cm; BMI: 21.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (4 samples)
- Sample HCM-CSHL-0768-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0768-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
- Sample HCM-CSHL-0768-C56-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
- Sample HCM-CSHL-0768-C56-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
